Somatic mutation profile of tumor specimen TCGA-BB-A6UM-01A (aliquot TCGA-BB-A6UM-01A-12D-A34J-08) from TCGA case TCGA-BB-A6UM, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 52.6 years (19,194 days).
Specimen TCGA-BB-A6UM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f037a76e-523f-4cf4-9e73-eed699dbaa99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-A6UM-10A (Blood Derived Normal), aliquot TCGA-BB-A6UM-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5294f9e9-63f1-4729-bac5-2c2bfb4ea04a

The open-access MAF lists 66 somatic variants for this specimen: 45 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 20, Nonsense Mutation 4, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 126/143 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 117/136 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.036); catalogued as rs769356878, COSV100718294; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3955A>G p.T1319A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV101000498; called by muse, mutect2, varscan2
- ADARB2 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as rs1190814178, COSV101186956; called by muse, mutect2, varscan2
- AMER2 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781271984, COSV63439693; called by muse, mutect2, varscan2
- ANKRD13C | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.656); catalogued as COSV99257121; called by muse, mutect2, varscan2
- BEND2 | c.2179C>T p.L727F | Missense Mutation (SNP) | VAF 83/106 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV101192066; called by muse, mutect2, varscan2
- CDH23 | c.3284T>C p.V1095A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1458043371, COSV99821459; called by muse, mutect2, varscan2
- CELSR2 | c.6304G>A p.V2102M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1323331645, COSV54781472; called by muse, mutect2, varscan2
- CFAP206 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV99739672; called by muse, mutect2, varscan2
- CLASP1 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99755195; called by muse, mutect2, varscan2
- COL6A3 | c.6408+1G>A p.X2136_splice | Splice Site (SNP) | VAF 120/339 reads (35%) | catalogued as COSV99798825; called by muse, mutect2, varscan2
- FAM83G | c.1342A>C p.K448Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV100525198; called by muse, mutect2
- FEM1B | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as COSV100183677; called by muse, mutect2, varscan2
- FSIP2 | c.18308A>G p.Q6103R | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV100555378; called by muse, mutect2, varscan2
- GEMIN5 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 53/115 reads (46%) | catalogued as rs773208129, COSV99593993; called by muse, mutect2, varscan2
- HSD17B1 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487778368, COSV56798205; called by muse, varscan2
- IBA57 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs761100484, COSV100812778; called by muse, mutect2, varscan2
- IGF2R | c.4928C>T p.P1643L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs769935757, COSV100807509; called by muse, mutect2, varscan2
- KIAA0100 | c.1948A>T p.T650S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV101197334; called by muse, mutect2, varscan2
- KIF7 | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs73477443, COSV51546832; called by muse, mutect2, varscan2
- KLHL38 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768991979, COSV100384424; called by muse, mutect2, varscan2
- KRT37 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs140701476, COSV56659104; called by muse, mutect2, varscan2
- KRTAP10-5 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs782719602, COSV59983196; called by muse, mutect2, varscan2
- LILRA1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs919874018, COSV52182057, COSV52185670; called by muse, varscan2
- LIN52 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101624996; called by muse, mutect2, varscan2
- LRP1B | c.11320T>C p.C3774R | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101257743; called by muse, mutect2, varscan2
- MAST1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263087; called by muse, mutect2, varscan2
- NCAPD2 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV100217260; called by muse, mutect2, varscan2
- NSUN6 | c.322A>T p.K108* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as rs1564806039, COSV101045701, COSV66033366; called by muse, mutect2, varscan2
- PCDHB5 | c.1202C>G p.T401S | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.262); catalogued as COSV50666945, COSV99167982; called by muse, mutect2, varscan2
- RBM12B | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as rs373893335; called by muse, mutect2, varscan2
- SEMA5A | c.2909A>G p.H970R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV101228446; called by muse, mutect2, varscan2
- SLC22A18 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs770190420, COSV100388837, COSV56542288; called by mutect2, varscan2
- SPAG17 | c.5689C>T p.Q1897* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100309351; called by muse, mutect2, varscan2
- SPAST | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs771455657, COSV100188586, COSV59518240; called by muse, mutect2, varscan2
- SUCLG2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs748940563, COSV56208975; called by muse, mutect2, varscan2
- THSD4 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs756810656, COSV99965719; called by muse, mutect2, varscan2
- THSD7A | c.4961A>T p.D1654V | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101349181; called by muse, mutect2, varscan2
- TMEM67 | c.2981T>C p.L994S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100019414; called by muse, mutect2, varscan2
- TRPV5 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144202979; called by muse, mutect2, varscan2
- UNC119 | c.498C>G p.Y166* | Nonsense Mutation (SNP) | VAF 50/143 reads (35%) | catalogued as COSV99971717; called by muse, mutect2, varscan2
- ZNF536 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751094459, COSV62825355; called by muse, mutect2, varscan2
- CNTNAP3 | c.3701A>G p.E1234G | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ACTB | c.18C>T p.A6= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs1188078226, COSV100079699; called by muse, mutect2, varscan2
- BCAR3 | c.297C>T p.H99= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs376407020; called by muse, mutect2, varscan2
- BRINP2 | c.1164G>A p.R388= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV100837841, COSV100838130; called by muse, mutect2
- CAMTA2 | c.1368C>T p.H456= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as rs370912778; called by muse, mutect2, varscan2
- CDKN1B | c.177G>A p.K59= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as rs140927518; called by muse, mutect2, varscan2
- ELP1 | c.3963C>T p.N1321= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV101010420; called by muse, mutect2, varscan2
- FKBP8 | c.762C>T p.S254= (on ENST00000222308 / NM_001308373.2; = p.S255= on NM_012181.5) | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs140514472; called by muse, mutect2, varscan2
- FOXO3 | c.1032G>A p.S344= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs760685861, COSV100669923; called by muse, mutect2, varscan2
- FRMD4B | c.1659C>T p.N553= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs757588162, COSV101273477; called by muse, mutect2, varscan2
- IGKV1D-8 | c.255T>C p.S85= | Silent (SNP) | VAF 61/210 reads (29%) | catalogued as rs762769677; called by muse, mutect2, varscan2
- KATNIP | c.4788C>T p.S1596= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs1055710374, COSV99851308; called by muse, mutect2, varscan2
- KIF3C | c.750C>T p.S250= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs775302858, COSV53099661; called by muse, mutect2, varscan2
- OR10G4 | c.99C>T p.Y33= | Silent (SNP) | VAF 55/80 reads (69%) | catalogued as rs774583054, COSV100304851; called by muse, mutect2, varscan2
- PCDHGA12 | c.963A>G p.A321= | Silent (SNP) | VAF 61/162 reads (38%) | catalogued as COSV99340559; called by muse, mutect2, varscan2
- SHOC2 | c.717C>T p.N239= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99510252; called by muse, mutect2, varscan2
- SLC25A52 | c.384T>C p.F128= (on ENST00000672005; = p.F118= on NM_001034172.4) | Silent (SNP) | VAF 80/208 reads (38%) | catalogued as rs969902687, COSV99329595; called by muse, mutect2, varscan2
- SLC43A2 | c.1530C>T p.L510= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100025015; called by muse, mutect2, varscan2
- ST3GAL6 | c.546G>A p.T182= | Silent (SNP) | VAF 44/192 reads (23%) | catalogued as rs747652874, COSV54580937; called by muse, mutect2, varscan2
- XKR8 | c.972C>T p.C324= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs1395940744, COSV100872030; called by muse, mutect2, varscan2
- ZBED9 | c.1377T>C p.I459= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV101509272; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579232 C>T | 5'Flank (SNP) | VAF 12/32 reads (38%) | catalogued as rs377334422; called by muse, varscan2
